CPTAC case C3L-00157 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/afb7729c-4ee9-4a64-8382-422dc3d8052f

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Year of birth: 1956; Vital status: Dead; Days to death: 1,396 days (3.8 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 60.6 years (22,118 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,396 days (3.8 years); Progression or recurrence: yes; Days to recurrence: 1,337 days (3.7 years); Days to last follow up: 1,396 days (3.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.2 cm (a second GDC size field records 10.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 17; Lymph nodes tested: 45; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 328 days; Disease response: Tumor Free.
- Days to follow up: 654 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,014 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,350 days (3.7 years); Disease response: With Tumor.
- Days to follow up: 1,396 days (3.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,337 days (3.7 years).
- Days to follow up: 1,396 days (3.8 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 92 kg; Height: 162.5 cm; BMI: 34.84.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00157-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 295 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00157-22: Section location: Anterior endometrium; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-00157-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3L-00157-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
